Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7370, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7370-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) LARYNX, LEFT SUPRAGLOTTIC, BIOPSY: MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

**Electronically Signed [REDACTED] **

CLINICAL DATA

Clinical Features: Malignant neoplasm of head, neck, and face

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) left supraglottic larynx (head and neck research)

GROSS DESCRIPTION:

1) SOURCE: Left Supraglottic Larynx

Received fresh labeled, "left supraglottic larynx," are two fragments of pale tan-pink soft tissue that are 1.0 x 1.0 x 0.4 cm in aggregate. A portion of each of these pieces is given to research. The remaining tissue is submitted entirely.

Summary of sections: 1A, 2/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

Source: NCI Genomic Data Commons file 597522a9-a7c6-4674-ba23-aa1e2348e733 (TCGA-CR-7370.F9156F28-47F0-4AE6-9913-7FA827553D61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).